Gene-level copy-number profile of tumor specimen TCGA-UT-A88G-01B from TCGA case TCGA-UT-A88G, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 73.1 years (26,704 days).
Specimen TCGA-UT-A88G-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.4d8963e9-7cfe-47d0-8bcf-75348b4e3585.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UT-A88G-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2f1b9ef6-d3b9-4b5b-8c8d-dcd25414b432

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 142; copy number 1: 1,445; copy number 2: 27,549; copy number 3: 15,383; copy number 4: 14,920; copy number 5: 381.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UT-A88G-01B-11D-A39Q-01): tumor purity 0.83, ploidy 2.81, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 141 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,341,669–31,645,160, 141 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 381 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:1,065,580–2,089,211, 8 genes, copy number 5: RN7SL120P, CNTN6, CRB3P1, RPL23AP38, RPL23AP39, RPL21P17, AC018814.1, RN7SKP144.
- chr3:2,110,409–2,144,241, 2 genes, copy number 5: CNTN4-AS2, AC087427.1.
- chr7:145,269,514–148,420,998, 15 genes, copy number 5 (within-gene range 4–5): AC004911.1, DPY19L4P2, AC006007.1, AC073308.1, CNTNAP2, AC073418.1, Y_RNA, CNTNAP2-AS1, DUTP3, RANP2, MIR548F4, AC005518.1, AC005518.2, RNU6-1184P, RNA5SP249.
- chr9:11,275,314–13,323,450, 18 genes, copy number 5: AL451129.1, AL355672.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1.
- chr9:13,406,380–13,488,125, 1 gene, copy number 5 (within-gene range 4–5): LINC01235.
- chr11:60,077,350–64,166,113, 199 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:31,363,481–33,718,217, 63 genes, copy number 5 (broad region; genes not listed).
- chr15:94,841,059–98,647,371, 66 genes, copy number 5 (broad region; genes not listed).
- chr20:51,596,514–52,204,308, 9 genes, copy number 5 (within-gene range 4–5): ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1.

Autosomal genes at a single copy (total copy number 1): 10. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
